Somatic mutation profile of tumor specimen C3N-03057-02 (aliquot CPT0236210006) from CPTAC case C3N-03057, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 61.4 years (22,417 days).
Specimen C3N-03057-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46963a7d-b110-4b94-a112-4908d55209f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03057-31 (Blood Derived Normal), aliquot CPT0236260002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57e622b9-9fed-4b85-86c0-cce2665d2fd9

The open-access MAF lists 84 somatic variants for this specimen: 55 protein-altering or splice-affecting, 21 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 21, Intron 4, 3'UTR 2, Splice Region 2, RNA 2, Frame Shift Ins 2, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 98/560 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ABHD13 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV65535064; called by muse, mutect2
- C1orf54 | c.166A>T p.I56L | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64859814; called by muse, mutect2
- CDYL2 | c.654T>A p.S218R | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs1211531545; called by muse, mutect2
- COL4A3 | c.768C>T p.D256= | Splice Region (SNP) | VAF 23/357 reads (6%) | catalogued as rs966583523; called by muse, mutect2
- EYA4 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.115); catalogued as rs1281362848, COSV100766193; called by muse, mutect2, varscan2
- F10 | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376163818, CM980650, COSV65023214; called by muse, mutect2, varscan2
- FLNA | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 49/408 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.93); catalogued as rs1287585684, COSV61048334; called by muse, mutect2, varscan2
- FLYWCH1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs376062192; called by muse, mutect2
- GGT5 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1026801373, COSV54068813; called by muse, mutect2, varscan2
- GLYCTK | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 46/390 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.107); catalogued as rs746478621, COSV59793018; called by muse, mutect2, varscan2
- IL21R | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1385136152, COSV61971760, COSV61973084; called by muse, mutect2, varscan2
- KANK4 | c.1249G>C p.D417H | Missense Mutation (SNP) | VAF 27/389 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV62989181; called by muse, mutect2
- KCNK15 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV65720163; called by muse, mutect2
- MEX3C | c.1123G>C p.G375R | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101346295; called by muse, mutect2, varscan2
- MUC16 | c.36469C>A p.L12157M | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs750617945; called by muse, mutect2
- NAV3 | c.2029G>C p.D677H | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57082953; called by muse, mutect2, varscan2
- NRXN3 | c.2464C>T p.R822C (on ENST00000335750 / NM_001330195.2; = p.R449C on NM_004796.6) | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs548908740, COSV59711740; called by muse, mutect2, varscan2
- PCDHA1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 56/747 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV65375661, COSV65376660; called by muse, mutect2
- POTEF | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 66/916 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.092); catalogued as rs1404772773; called by muse, mutect2
- RABGGTA | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs367971962; called by mutect2, varscan2
- SLC24A4 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 134/516 reads (26%) | catalogued as rs141131742, COSV100104480; called by muse, mutect2, varscan2
- SORCS3 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762674027, COSV63804506; called by muse, mutect2
- TAOK2 | c.3073G>A p.A1025T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as rs1261463041, COSV54229630; called by muse, mutect2
- TP53 | c.805dup p.S269Kfs*3 | Frame Shift Ins (INS) | VAF 100/446 reads (22%) | catalogued as COSV53051061; called by mutect2, varscan2
- TP53 | c.804delinsGA p.N268Kfs*4 | Frame Shift Ins (INS) | VAF 60/486 reads (12%) | catalogued as COSV53086682, COSV53241270; called by mutect2*, pindel, varscan2*
- TTC3 | c.3724G>A p.A1242T | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1335480413; called by muse, mutect2
- ZNF560 | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.824); catalogued as COSV56865568; called by muse, mutect2, varscan2
- AGRN | c.5602G>A p.A1868T | Missense Mutation (SNP) | VAF 42/704 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2
- ARSF | c.931T>C p.Y311H | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHERP | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CYP2W1 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DHX58 | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- DNAH2 | c.606C>G p.H202Q | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.072); called by muse, mutect2
- ERN1 | c.54+1G>T p.X18_splice | Splice Site (SNP) | VAF 13/171 reads (8%) | called by muse, mutect2
- FOXA3 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 101/329 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GUCY1B1 | c.1154A>G p.D385G | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2
- HLA-DMB | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCND2 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); called by muse, mutect2
- LAT2 | c.356A>G p.Y119C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2
- MBD5 | c.3304G>T p.V1102F | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- NSUN4 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR1F1 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 43/341 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OXSM | c.1280T>C p.L427P | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.763); called by muse, mutect2
- PEX2 | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- RET | c.1150_1157del p.P384Gfs*83 | Frame Shift Del (DEL) | VAF 117/345 reads (34%) | called by mutect2, pindel, varscan2
- SEC23A | c.2098T>C p.F700L | Missense Mutation (SNP) | VAF 26/387 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); called by muse, mutect2
- SLC22A10 | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2
- SLC25A13 | c.1132T>G p.F378V | Missense Mutation (SNP) | VAF 42/527 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2
- TMEM184C | c.334A>T p.T112S | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TRBV5-1 | c.48A>C p.A16= | Splice Region (SNP) | VAF 11/165 reads (7%) | called by muse, mutect2
- TTC3 | c.3519G>C p.K1173N | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- TTC3 | c.4189G>A p.G1397S | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.356); called by muse, mutect2
- ZNF432 | c.880T>A p.C294S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZSCAN12 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2
- AKAP9 | c.4413T>A p.T1471= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2
- C6orf15 | c.579A>G p.Q193= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs764688969; called by muse, mutect2, varscan2
- CACNG8 | c.726G>A p.L242= | Silent (SNP) | VAF 29/682 reads (4%) | catalogued as rs779285708; called by muse, mutect2
- CARMIL2 | c.4122G>A p.R1374= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- CLMN | c.2241G>A p.P747= | Silent (SNP) | VAF 25/320 reads (8%) | catalogued as rs749325647, COSV54181379; called by muse, mutect2
- GARRE1 | c.1899G>A p.K633= | Silent (SNP) | VAF 24/270 reads (9%) | called by muse, mutect2
- HFM1 | c.648T>C p.S216= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as rs528933492; called by muse, mutect2, varscan2
- KCNS2 | c.468C>T p.N156= | Silent (SNP) | VAF 28/522 reads (5%) | catalogued as rs199526084, COSV54641512; called by muse, mutect2
- KMT2A | c.7570C>T p.L2524= | Silent (SNP) | VAF 65/229 reads (28%) | called by muse, mutect2, varscan2
- MMEL1 | c.1407A>G p.R469= | Silent (SNP) | VAF 45/151 reads (30%) | called by muse, varscan2
- NOTCH2 | c.3690C>G p.A1230= | Silent (SNP) | VAF 88/543 reads (16%) | called by muse, mutect2, varscan2
- NSD3 | c.3151T>C p.L1051= | Silent (SNP) | VAF 12/118 reads (10%) | called by mutect2, varscan2
- PAQR4 | c.327C>T p.S109= | Silent (SNP) | VAF 68/494 reads (14%) | catalogued as rs1341980024; called by muse, mutect2, varscan2
- PCDHA6 | c.228G>A p.E76= | Silent (SNP) | VAF 68/852 reads (8%) | catalogued as rs573520958; called by muse, mutect2
- PMFBP1 | c.480G>A p.A160= | Silent (SNP) | VAF 22/369 reads (6%) | catalogued as rs373109383; called by muse, mutect2
- RAB11FIP2 | c.1461G>A p.R487= | Silent (SNP) | VAF 54/374 reads (14%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.975G>A p.S325= (on ENST00000291707 / NM_053003.4; = p.S207= on NM_033329.2) | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as rs58092569, COSV52462594; called by muse, mutect2, varscan2
- SLC6A9 | c.1404G>A p.L468= (on ENST00000360584 / NM_201649.4; = p.L414= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- STING1 | c.687C>T p.T229= | Silent (SNP) | VAF 82/230 reads (36%) | catalogued as rs749344150; called by muse, mutect2, varscan2
- WASHC4 | c.252C>T p.N84= | Silent (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- ZNF546 | c.2175A>G p.E725= | Silent (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- ABCC6 | c.2787+36T>A | Intron (SNP) | VAF 79/253 reads (31%) | called by muse, varscan2
- ENTPD1 | c.1188+24C>A | Intron (SNP) | VAF 28/336 reads (8%) | called by muse, mutect2
- IGFN1 | c.*28A>G | 3'UTR (SNP) | VAF 24/325 reads (7%) | called by muse, mutect2
- OR7E5P | n.124A>T | RNA (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
- PARK7 | c.322+44G>A | Intron (SNP) | VAF 72/434 reads (17%) | catalogued as rs779375268; called by muse, mutect2, varscan2
- SSPOP | n.13552A>T | RNA (SNP) | VAF 61/198 reads (31%) | catalogued as rs778630883; called by muse, mutect2, varscan2
- TMEM135 | c.*508C>T | 3'UTR (SNP) | VAF 54/1460 reads (4%) | called by muse, mutect2
- ZNF205 | c.271+33A>C | Intron (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
